Somatic mutation profile of tumor specimen TCGA-29-2434-01A (aliquot TCGA-29-2434-01A-01D-1526-09) from TCGA case TCGA-29-2434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.0 years (18,997 days).
Specimen TCGA-29-2434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aec198b-d19f-4def-9df3-227a3f43a2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2434-10A (Blood Derived Normal), aliquot TCGA-29-2434-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce22c57d-58b7-42b7-a168-208ea89d1514

The open-access MAF lists 122 somatic variants for this specimen: 99 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 20, Frame Shift Del 5, Splice Site 3, Nonsense Mutation 3, In Frame Del 3, Intron 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRE11 | c.1327-2A>G p.X443_splice | Splice Site (SNP) | VAF 70/186 reads (38%) | catalogued as rs878854776, COSV60578129; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 170/193 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.3213C>A p.S1071R | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55955403; called by muse, mutect2, varscan2
- AC006059.2 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 104/530 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59607967; called by muse, mutect2, varscan2
- ADCY7 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 82/638 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268347; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 200/1316 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58444808; called by muse, mutect2, varscan2
- AIFM3 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59001031; called by muse, mutect2, varscan2
- ASH1L | c.7546C>T p.L2516F (on ENST00000368346 / NM_001366177.2; = p.L2511F on NM_018489.3) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100853644; called by muse, mutect2, varscan2
- ASH1L | c.7545G>A p.M2515I (on ENST00000368346 / NM_001366177.2; = p.M2510I on NM_018489.3) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.944); catalogued as COSV100853645; called by muse, mutect2, varscan2
- ASIC4 | c.855+2T>A p.X285_splice | Splice Site (SNP) | VAF 41/182 reads (23%) | catalogued as COSV61732411; called by muse, mutect2, varscan2
- ATP10D | c.4060G>A p.G1354R | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56694251; called by muse, mutect2, varscan2
- ATP1A4 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 223/835 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150693480; called by muse, mutect2, varscan2
- AVL9 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV56167694; called by muse, mutect2, varscan2
- BAMBI | c.19T>A p.Y7N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.266); catalogued as COSV65003148; called by muse, mutect2, varscan2
- BCAM | c.809G>A p.W270* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV54303240; called by muse, mutect2, varscan2
- BMP4 | c.1210G>C p.G404R | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55416479; called by muse, mutect2, varscan2
- BRWD1 | c.3899G>T p.R1300I | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV60898832; called by muse, mutect2, varscan2
- C16orf72 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.775); catalogued as COSV59916438; called by muse, mutect2, varscan2
- C1orf162 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV59059374; called by muse, mutect2, varscan2
- CATSPERE | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs573139470, COSV63677138; called by muse, mutect2, varscan2
- CDCA4 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 92/462 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV60315683; called by muse, mutect2, varscan2
- CEP250 | c.4243C>G p.Q1415E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.022); catalogued as COSV100698920, COSV61171456; called by muse, mutect2, varscan2
- CNOT3 | c.1608C>T p.A536= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as COSV55365311; called by muse, mutect2, varscan2
- COG4 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV60423679, COSV60424137; called by muse, mutect2, varscan2
- CR2 | c.1649C>A p.T550N | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs758980063, COSV65508462; called by muse, varscan2
- CREB5 | c.7T>G p.Y3D | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100745751; called by muse, mutect2
- DDI2 | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60780316; called by muse, mutect2, varscan2
- DIAPH2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV61277524; called by muse, mutect2, varscan2
- DLG3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as rs1485486750, COSV52084272; called by muse, mutect2, varscan2
- DNAH8 | c.7936A>T p.K2646* | Nonsense Mutation (SNP) | VAF 54/146 reads (37%) | catalogued as COSV59460230; called by muse, mutect2, varscan2
- EBPL | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 70/227 reads (31%) | catalogued as COSV54432737; called by muse, mutect2, varscan2
- EGFLAM | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59307972; called by muse, mutect2, varscan2
- EIF4G1 | c.3626G>C p.S1209T (on ENST00000346169 / NM_198241.3; = p.S1014T on NM_004953.5) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV59992100; called by muse, mutect2, varscan2
- EML1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV51748057; called by muse, mutect2, varscan2
- EVC2 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 280/485 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV60396747; called by muse, mutect2, varscan2
- FAM171B | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs369639086; called by muse, mutect2, varscan2
- FEM1B | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100183777; called by muse, mutect2
- FLVCR2 | c.1507A>T p.N503Y | Missense Mutation (SNP) | VAF 295/329 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV53163138; called by muse, mutect2, varscan2
- FTO | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM108750, COSV67112710; called by muse, mutect2, varscan2
- GBP4 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as COSV63255014; called by muse, mutect2, varscan2
- GRM3 | c.1136T>G p.I379S | Missense Mutation (SNP) | VAF 95/549 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); catalogued as COSV64474766; called by muse, mutect2, varscan2
- HPS3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 91/534 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as rs762633341, COSV56055576; called by muse, mutect2, varscan2
- HSPD1 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52099268; called by muse, mutect2, varscan2
- KDR | c.2051T>A p.I684N | Missense Mutation (SNP) | VAF 312/554 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55769153; called by muse, mutect2, varscan2
- KMT2C | c.12935C>A p.A4312D | Missense Mutation (SNP) | VAF 177/763 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51459985; called by muse, mutect2, varscan2
- KPNA4 | c.974G>C p.C325S | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV62076229; called by muse, mutect2, varscan2
- LAMA5 | c.1617G>C p.Q539H | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV53363964; called by muse, mutect2, varscan2
- LAMB2 | c.4403C>T p.A1468V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59735174; called by muse, mutect2, varscan2
- LIPJ | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV64245783; called by muse, mutect2, varscan2
- MAP3K19 | c.3459C>A p.N1153K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV59636590; called by muse, mutect2, varscan2
- MAP3K7CL | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.421); catalogued as rs752198255, COSV54510630; called by muse, mutect2, varscan2
- MEGF8 | c.4077C>G p.D1359E (on ENST00000251268 / NM_001271938.2; = p.D1292E on NM_001410.3) | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV99239734; called by muse, mutect2
- MMP3 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 159/392 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV55406829; called by muse, mutect2, varscan2
- NEURL1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as rs1027115656, COSV63914969; called by muse, mutect2, varscan2
- NOC4L | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs141988623; called by muse, mutect2, varscan2
- NPAP1 | c.1519T>A p.F507I | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV61508572; called by muse, mutect2, varscan2
- NRXN3 | c.2152G>A p.A718T (on ENST00000335750 / NM_001330195.2; = p.A345T on NM_004796.6) | Missense Mutation (SNP) | VAF 303/343 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59769447; called by muse, mutect2, varscan2
- OR10T2 | c.732T>G p.H244Q | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs779154952, COSV57782130; called by muse, mutect2, varscan2
- OR4D9 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61434984; called by muse, mutect2, varscan2
- OR5A1 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57377247; called by muse, mutect2, varscan2
- PCDHB6 | c.1440C>G p.I480M | Missense Mutation (SNP) | VAF 15/475 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV99173312; called by muse, mutect2
- PIK3R5 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 381/412 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52655600; called by muse, mutect2, varscan2
- PKD1 | c.6196C>G p.L2066V | Missense Mutation (SNP) | VAF 60/63 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51919773; called by muse, mutect2, varscan2
- PLEKHA5 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54704863; called by muse, mutect2, varscan2
- PLXNA3 | c.521A>T p.K174M | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV63754659; called by muse, mutect2, varscan2
- PODN | c.1457C>T p.S486L (on ENST00000395871; = p.S438L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1557656592, COSV57014967; called by muse, mutect2, varscan2
- POFUT2 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs1203626852, COSV57959784; called by muse, mutect2, varscan2
- POM121 | c.3383G>C p.S1128T (on ENST00000434423; = p.S863T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs782364588, COSV57518976; called by muse, mutect2, varscan2
- PPL | c.2076G>C p.E692D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV62048417; called by muse, mutect2, varscan2
- PREX1 | c.4806G>C p.L1602F | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906909; called by muse, mutect2
- RASGRF2 | c.2623T>C p.S875P | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54133142; called by muse, mutect2, varscan2
- RNF138 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55234647; called by muse, mutect2, varscan2
- SCGN | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 137/380 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58546168; called by muse, mutect2, varscan2
- SCN1A | c.5147G>A p.C1716Y (on ENST00000303395 / NM_001202435.3; = p.C1705Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/535 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57676209; called by muse, mutect2, varscan2
- SLC2A14 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 174/1235 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs113584214, COSV61587235; called by muse, mutect2, varscan2
- SLC2A8 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1351964980, COSV64894759; called by muse, mutect2, varscan2
- SLC35G2 | c.590T>C p.M197T | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs1345683982, COSV67588587; called by muse, mutect2, varscan2
- SLFN5 | c.822A>G p.I274M | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as COSV55482055; called by muse, mutect2, varscan2
- STEAP3 | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV61529739; called by muse, mutect2, varscan2
- SUSD2 | c.1492A>C p.T498P | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV64204549; called by muse, mutect2, varscan2
- SYCP2 | c.3010G>T p.D1004Y | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV62769718; called by muse, mutect2, varscan2
- SYNGR4 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.184); catalogued as rs752596742, COSV61225581; called by muse, mutect2, varscan2
- SYNPO2 | c.3316T>A p.W1106R | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.281); catalogued as COSV61113568; called by muse, mutect2, varscan2
- TFPT | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1162947527, COSV58085923; called by muse, mutect2, varscan2
- TLR9 | c.1212C>A p.N404K | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.116); catalogued as COSV62347419; called by muse, mutect2, varscan2
- TRIM46 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55279459; called by muse, mutect2, varscan2
- UGT2A3 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs753497145, COSV52360924; called by muse, mutect2, varscan2
- WNT7A | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53200266; called by muse, mutect2, varscan2
- ZNF318 | c.4724G>A p.S1575N | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767009982, COSV58934250; called by muse, mutect2, varscan2
- ZNF318 | c.2026C>A p.L676I | Missense Mutation (SNP) | VAF 229/976 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV58934258; called by muse, mutect2, varscan2
- AC244197.3 | c.127_134del p.E43* | Frame Shift Del (DEL) | VAF 85/449 reads (19%) | called by mutect2, pindel, varscan2
- C19orf47 | c.906_921del p.A303Sfs*4 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by pindel, varscan2*
- CDC5L | c.522del p.K174Nfs*23 | Frame Shift Del (DEL) | VAF 79/313 reads (25%) | called by mutect2, pindel, varscan2
- CEP89 | c.2290_2319del p.D764_S773del | In Frame Del (DEL) | VAF 53/322 reads (16%) | called by mutect2, pindel, varscan2
- FUT11 | c.896_908del p.L299Pfs*9 | Frame Shift Del (DEL) | VAF 176/203 reads (87%) | called by mutect2, pindel, varscan2
- HGD | c.273_282+4del p.X91_splice | Splice Site (DEL) | VAF 47/269 reads (17%) | called by mutect2, pindel, varscan2
- NOX3 | c.1378_1401del p.E460_G467del | In Frame Del (DEL) | VAF 33/199 reads (17%) | called by mutect2, pindel, varscan2
- PLEKHM1 | c.1018_1032del p.S340_L344del | In Frame Del (DEL) | VAF 78/283 reads (28%) | called by mutect2, pindel, varscan2
- UGT1A10 | c.3_19del p.M1_?7 | Frame Shift Del (DEL) | VAF 51/200 reads (26%) | called by mutect2, pindel, varscan2
- ADCY9 | c.2898G>A p.S966= | Silent (SNP) | VAF 55/61 reads (90%) | catalogued as rs769823999, COSV53577734; called by muse, mutect2, varscan2
- ADGRB3 | c.432A>G p.K144= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs754370767, COSV65404422; called by muse, mutect2, varscan2
- ANAPC1 | c.3780A>G p.V1260= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV61977325; called by muse, mutect2, varscan2
- ATP13A5 | c.1650C>G p.L550= | Silent (SNP) | VAF 201/300 reads (67%) | catalogued as rs1456793113, COSV60871417; called by muse, mutect2, varscan2
- CDH9 | c.387G>A p.K129= | Silent (SNP) | VAF 40/384 reads (10%) | catalogued as rs760586873, COSV50250712, COSV50256408, COSV50324932; called by muse, mutect2
- CFAP61 | c.1728G>A p.K576= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as COSV55625042; called by muse, mutect2, varscan2
- EIF4A1 | c.1161T>C p.I387= | Silent (SNP) | VAF 57/220 reads (26%) | catalogued as COSV51511339; called by muse, mutect2, varscan2
- FPR1 | c.228C>T p.S76= | Silent (SNP) | VAF 211/444 reads (48%) | catalogued as COSV59052239; called by muse, mutect2, varscan2
- IL26 | c.36G>T p.L12= | Silent (SNP) | VAF 263/599 reads (44%) | catalogued as COSV57489351; called by muse, mutect2, varscan2
- MAIP1 | c.6G>A p.A2= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV54461003; called by muse, mutect2, varscan2
- ME1 | c.423A>G p.P141= | Silent (SNP) | VAF 122/276 reads (44%) | catalogued as rs1309470289, COSV63840496; called by muse, mutect2, varscan2
- SAMD7 | c.807C>G p.T269= | Silent (SNP) | VAF 61/536 reads (11%) | catalogued as rs765222563, COSV59419711; called by muse, mutect2, varscan2
- SEC23A | c.360A>G p.V120= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56975786; called by muse, mutect2, varscan2
- SLC4A2 | c.2490G>A p.L830= | Silent (SNP) | VAF 204/983 reads (21%) | catalogued as rs748945851, COSV52540815; called by muse, mutect2, varscan2
- SLC6A8 | c.855C>A p.A285= | Silent (SNP) | VAF 87/320 reads (27%) | catalogued as COSV53472712; called by muse, mutect2, varscan2
- STAR | c.729C>G p.L243= | Silent (SNP) | VAF 123/320 reads (38%) | catalogued as COSV52417870; called by muse, mutect2, varscan2
- TARDBP | c.225C>G p.V75= | Silent (SNP) | VAF 58/205 reads (28%) | catalogued as COSV53570402; called by muse, mutect2, varscan2
- TMC1 | c.1914C>T p.G638= | Silent (SNP) | VAF 204/666 reads (31%) | catalogued as COSV52778894; called by muse, mutect2, varscan2
- TRIM24 | c.2037A>C p.V679= (on ENST00000343526 / NM_015905.3; = p.V645= on NM_003852.4) | Silent (SNP) | VAF 117/1194 reads (10%) | catalogued as COSV58974355; called by muse, mutect2
- VPS13A | c.8349T>C p.S2783= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV62432724; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840304 C>T | 5'Flank (SNP) | VAF 92/131 reads (70%) | catalogued as COSV100007421, COSV58339548; called by muse, mutect2, varscan2
- ATP11A | c.*10-19C>G | Intron (SNP) | VAF 153/363 reads (42%) | catalogued as COSV52115885; called by muse, mutect2, varscan2
- USH1C | c.1284+6966G>A | Intron (SNP) | VAF 75/293 reads (26%) | catalogued as COSV50014118, COSV50022583; called by muse, mutect2, varscan2
